Somatic mutation profile of tumor specimen MBCProject_0984_T2_WES (aliquot MBCProject_0984_T2_WES_1) from CMI case MBCProject_0984, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Tissue or organ of origin: Breast, NOS.
Specimen MBCProject_0984_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a090e668-fc98-4501-80a6-b0c394423d43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0984_SALIVA (Saliva), aliquot MBCProject_0984_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6bc3a11-5577-46f4-bca5-ab0149e77a60

The open-access MAF lists 58 somatic variants for this specimen: 40 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 15, Intron 2, Frame Shift Ins 1, Splice Region 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 102/153 reads (67%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AIPL1 | c.146T>C p.I49T | Missense Mutation (SNP) | VAF 74/100 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs1172466966; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL24A1 | c.112C>A p.Q38K | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.237); catalogued as COSV65309110; called by muse, mutect2, varscan2
- FAT1 | c.6508G>A p.V2170I | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.593); catalogued as rs377169844; called by muse, mutect2, varscan2
- FREM1 | c.2133G>T p.K711N | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66525399; called by muse, mutect2, varscan2
- HNRNPR | c.1829A>G p.Y610C | Missense Mutation (SNP) | VAF 53/70 reads (76%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.52); catalogued as rs772666188, COSV56421561; called by muse, mutect2, varscan2
- PCDHGB1 | c.1910G>A p.R637H | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs1446316732, COSV53982366; called by muse, mutect2, varscan2
- PREX2 | c.3851C>T p.A1284V | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs375506738; called by muse, mutect2, varscan2
- PSME4 | c.4439C>T p.P1480L | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV66364594; called by muse, mutect2
- SPTAN1 | c.6017G>C p.R2006P | Missense Mutation (SNP) | VAF 68/271 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV63987850; called by muse, mutect2, varscan2
- STARD6 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs1339772806, COSV57141602; called by muse, mutect2
- WDR90 | c.4606G>A p.D1536N | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as rs752490026; called by muse, mutect2, varscan2
- ADGRF3 | c.2581G>A p.A861T (on ENST00000311519 / NM_001145168.1; = p.A662T on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- ADGRG4 | c.5674C>A p.Q1892K | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ARHGAP30 | c.2326G>A p.D776N | Missense Mutation (SNP) | VAF 75/136 reads (55%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1S | c.826C>A p.L276I | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CEP290 | c.7064A>T p.K2355I | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- CHRM3 | c.205G>C p.V69L | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.271); called by muse, mutect2
- COL4A4 | c.3305C>T p.S1102F | Missense Mutation (SNP) | VAF 74/189 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL9A3 | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DEFB115 | c.8C>A p.P3Q | Missense Mutation (SNP) | VAF 58/151 reads (38%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.015); called by muse, varscan2
- DNAH14 | c.4748T>C p.V1583A (on ENST00000445597; = p.V1988A on NM_001367479.1) | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DYNC1H1 | c.8637+4G>T | Splice Region (SNP) | VAF 106/337 reads (31%) | called by muse, mutect2, varscan2
- FER1L5 | c.2992C>T p.R998C (on ENST00000623019; = p.R1005C on NM_001293083.2) | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- GATA3 | c.1236dup p.S413Qfs*94 | Frame Shift Ins (INS) | VAF 25/109 reads (23%) | called by mutect2, pindel, varscan2
- H1-3 | c.154T>C p.S52P | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HES1 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- KIF3B | c.1816G>T p.D606Y | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- LDLRAD3 | c.360C>G p.C120W | Missense Mutation (SNP) | VAF 71/110 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LHX2 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- LRBA | c.7887A>T p.R2629S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, varscan2
- MED1 | c.3419C>G p.S1140C | Missense Mutation (SNP) | VAF 204/4006 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.527); called by muse, mutect2
- N4BP1 | c.1614G>C p.M538I | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR4C6 | c.905A>C p.K302T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- PLXNB2 | c.2233T>G p.Y745D | Missense Mutation (SNP) | VAF 88/219 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEC24A | c.2242G>A p.V748I | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- SLC34A3 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTN | c.87781G>A p.A29261T (on ENST00000591111; = p.A21837T on NM_003319.4) | Missense Mutation (SNP) | VAF 32/275 reads (12%) | PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- VCL | c.486G>T p.K162N | Missense Mutation (SNP) | VAF 69/499 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- XKR4 | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- AFF1 | c.3099A>G p.K1033= | Silent (SNP) | VAF 26/118 reads (22%) | called by muse, mutect2, varscan2
- CEP57L1 | c.1248A>T p.S416= | Silent (SNP) | VAF 120/940 reads (13%) | called by muse, mutect2, varscan2
- CLTCL1 | c.2874C>T p.H958= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as rs782380909, COSV54225286; called by muse, mutect2
- DKC1 | c.6G>A p.A2= | Silent (SNP) | VAF 116/301 reads (39%) | called by muse, mutect2, varscan2
- EPX | c.327C>T p.S109= | Silent (SNP) | VAF 16/226 reads (7%) | catalogued as rs757161947, COSV56596745; called by muse, mutect2
- GYG2 | c.555C>T p.H185= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs1343195404, COSV58552336; called by muse, mutect2, varscan2
- MASP2 | c.387G>T p.G129= | Silent (SNP) | VAF 87/114 reads (76%) | catalogued as rs199936343; called by muse, mutect2, varscan2
- NUP133 | c.2538C>T p.L846= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV54574910; called by muse, mutect2
- PCDHA13 | c.1326G>A p.S442= | Silent (SNP) | VAF 182/492 reads (37%) | catalogued as COSV56483414; called by muse, mutect2, varscan2
- PRR23B | c.387C>T p.G129= | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as COSV61493900; called by muse, mutect2, varscan2
- PTPN3 | c.2436C>T p.H812= | Silent (SNP) | VAF 25/130 reads (19%) | catalogued as rs775732806, COSV99356115; called by muse, mutect2, varscan2
- SPAG6 | c.1365C>T p.G455= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as rs1233758302; called by muse, mutect2, varscan2
- TGFB1 | c.1089G>A p.P363= | Silent (SNP) | VAF 34/62 reads (55%) | called by muse, mutect2, varscan2
- WDR62 | c.2319G>T p.R773= | Silent (SNP) | VAF 32/188 reads (17%) | called by muse, mutect2, varscan2
- ZSCAN10 | c.1554G>A p.T518= (on ENST00000252463; = p.T573= on NM_032805.3) | Silent (SNP) | VAF 44/119 reads (37%) | catalogued as rs747884734; called by muse, mutect2, varscan2
- AC008397.2 | c.-88G>A | 5'UTR (SNP) | VAF 32/41 reads (78%) | catalogued as COSV62747750; called by muse, mutect2, varscan2
- MORF4L1 | c.466+72A>T | Intron (SNP) | VAF 52/118 reads (44%) | called by muse, mutect2, varscan2
- ZNF606 | c.-52+514G>A | Intron (SNP) | VAF 44/219 reads (20%) | catalogued as rs1276857869; called by muse, mutect2, varscan2
